Somatic mutation profile of tumor specimen ALCH-B3FG-TTP1-B (aliquot ALCH-B3FG-TTP1-B-1-0-D-A78R-36) from ALCHEMIST case ALCH-B3FG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.8 years (23,658 days).
Specimen ALCH-B3FG-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e37227b-8c28-4dd0-94d1-efb9ed57f88a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3FG-NB1-A (Blood Derived Normal), aliquot ALCH-B3FG-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3a33b51-73a3-45a4-93f0-788f2895355f

The open-access MAF lists 112 somatic variants for this specimen: 67 protein-altering or splice-affecting, 34 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 34, Intron 5, 3'UTR 4, Nonsense Mutation 3, Splice Site 1, Splice Region 1, Frame Shift Ins 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 42/624 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ATM | c.6434A>T p.E2145V | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as rs1255710647; called by muse, mutect2
- CDH18 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 30/387 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56943479; called by muse, mutect2
- CLC | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774290465; called by muse, mutect2
- CRHR1 | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as COSV99523562; called by muse, mutect2
- CST3 | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 27/659 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149051742; called by muse, mutect2
- CTNNA3 | c.326C>A p.T109K | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV57717831; called by muse, mutect2
- ELFN1 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1292505097; called by muse, mutect2
- EPHA3 | c.2444G>T p.W815L | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100349760; called by muse, mutect2
- EPSTI1 | c.937G>T p.G313C (on ENST00000398762 / NM_001330543.2; = p.G302C on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/632 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58046074; called by muse, mutect2
- FSCB | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV61217816; called by muse, mutect2
- GRIN2A | c.2721G>T p.M907I | Missense Mutation (SNP) | VAF 33/798 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV58020400; called by muse, mutect2
- HOXB13 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99285428; called by muse, mutect2
- ITIH5 | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 20/580 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs1391395627; called by muse, mutect2
- KCNMA1 | c.2267-8A>G | Splice Region (SNP) | VAF 38/870 reads (4%) | catalogued as rs1323059370; called by muse, mutect2
- KIAA0825 | c.3533C>T p.T1178I | Missense Mutation (SNP) | VAF 14/347 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as rs1217574265, COSV70253470; called by muse, mutect2
- NPAS4 | c.1295G>C p.G432A | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV60649164, COSV60653254; called by muse, mutect2
- OR10C1 | c.704G>T p.R235L (on ENST00000622521; = p.R233L on NM_013941.3) | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs771138562, COSV101010813, COSV65822160; called by muse, mutect2
- OR4D9 | c.567C>A p.C189* | Nonsense Mutation (SNP) | VAF 35/328 reads (11%) | catalogued as COSV100259913; called by muse, mutect2, varscan2
- PTPRO | c.559T>A p.Y187N | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55524630; called by muse, mutect2
- SETD2 | c.4945G>T p.G1649W | Missense Mutation (SNP) | VAF 11/309 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57445233; called by muse, mutect2
- TAS2R40 | c.542C>A p.T181K | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV68818422, COSV68818797; called by muse, mutect2
- TGS1 | c.2029A>G p.I677V | Missense Mutation (SNP) | VAF 68/532 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs1295751183; called by muse, mutect2, varscan2
- ULK3 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1022064109, COSV101475542, COSV71348056; called by muse, mutect2
- UNC13B | c.4147G>T p.D1383Y | Missense Mutation (SNP) | VAF 13/331 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1165124784; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.757T>G p.L253V | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); called by muse, mutect2
- ASPM | c.1556G>A p.R519K | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.05); called by muse, mutect2
- ATP4A | c.475T>A p.Y159N | Missense Mutation (SNP) | VAF 15/355 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BICRA | c.2080G>C p.D694H | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- BPNT2 | c.808+1G>T p.X270_splice | Splice Site (SNP) | VAF 54/517 reads (10%) | called by muse, mutect2, varscan2
- C16orf92 | c.123G>T p.W41C | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); called by muse, mutect2
- CASP2 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); called by muse, mutect2
- CD163L1 | c.3890G>T p.R1297M | Missense Mutation (SNP) | VAF 38/650 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.416); called by muse, mutect2
- CD86 | c.145A>C p.S49R (on ENST00000330540 / NM_175862.5; = p.S43R on NM_006889.4) | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL15A1 | c.1871C>G p.P624R | Missense Mutation (SNP) | VAF 23/322 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCLRE1C | c.2023G>T p.A675S (on ENST00000378278 / NM_001350965.2; = p.A560S on NM_022487.4) | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); called by muse, mutect2
- DROSHA | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 48/805 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- FREM3 | c.3317T>C p.L1106P | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- GIP | c.65A>T p.E22V | Missense Mutation (SNP) | VAF 40/440 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2
- HMCN2 | c.14003G>A p.R4668K | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.012); called by muse, mutect2
- HSPG2 | c.10312G>T p.G3438C | Missense Mutation (SNP) | VAF 7/208 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRTAP20-3 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); called by muse, mutect2
- LPA | c.3590C>A p.P1197Q | Missense Mutation (SNP) | VAF 38/695 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LTBP1 | c.3635G>A p.C1212Y (on ENST00000404816 / NM_206943.4; = p.C886Y on NM_000627.4) | Missense Mutation (SNP) | VAF 28/373 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP6 | c.657dup p.G220Rfs*85 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by pindel, varscan2
- MTUS2 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 12/329 reads (4%) | called by muse, mutect2
- NBAS | c.4933G>A p.A1645T | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR5D18 | c.111T>G p.N37K | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- OR8G2P | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); called by muse, mutect2
- PCDH11X | c.119T>A p.I40K | Missense Mutation (SNP) | VAF 52/794 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA3 | c.1404C>A p.N468K | Missense Mutation (SNP) | VAF 16/407 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLCB2 | c.2181C>A p.N727K | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLXND1 | c.1505G>T p.S502I | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2
- RBM27 | c.2851G>T p.G951C | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- RTL1 | c.682C>G p.P228A | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- S100A3 | c.82A>G p.K28E | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, mutect2
- SGCD | c.451G>C p.A151P (on ENST00000435422 / NM_001128209.2; = p.A152P on NM_000337.5) | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIGLEC14 | c.1098G>T p.M366I | Missense Mutation (SNP) | VAF 17/377 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); called by muse, mutect2
- SLC34A1 | c.1196G>T p.W399L | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC34A1 | c.1197G>T p.W399C | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC34A1 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SOX2 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); called by muse, mutect2
- SPATA31A3 | c.1817G>T p.W606L | Missense Mutation (SNP) | VAF 30/832 reads (4%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.583); called by muse, mutect2
- TENM2 | c.297C>G p.D99E | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.028); called by muse, mutect2
- WDHD1 | c.94G>T p.G32* | Nonsense Mutation (SNP) | VAF 36/392 reads (9%) | called by muse, mutect2
- ZNF300 | c.497C>A p.P166Q | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- ZNF616 | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- ASB4 | c.1173C>A p.A391= | Silent (SNP) | VAF 8/198 reads (4%) | catalogued as COSV57945734; called by muse, mutect2
- BIVM-ERCC5 | c.4554A>G p.L1518= | Silent (SNP) | VAF 12/241 reads (5%) | catalogued as rs897050879; called by muse, mutect2
- CDH9 | c.369G>C p.L123= | Silent (SNP) | VAF 20/710 reads (3%) | called by muse, mutect2
- CFAP45 | c.1303C>T p.L435= | Silent (SNP) | VAF 22/438 reads (5%) | catalogued as COSV63650397; called by muse, mutect2
- CTNND2 | c.99C>A p.P33= | Silent (SNP) | VAF 26/484 reads (5%) | catalogued as COSV58864812; called by muse, mutect2
- DCX | c.999C>A p.P333= (on ENST00000636035 / NM_001195553.2; = p.P328= on NM_000555.3) | Silent (SNP) | VAF 24/482 reads (5%) | catalogued as COSV57575443; called by muse, mutect2
- ERC1 | c.3141A>T p.P1047= (on ENST00000360905 / NM_178040.4; = p.P1019= on NM_178039.4) | Silent (SNP) | VAF 31/550 reads (6%) | called by muse, mutect2
- FANCM | c.2214G>T p.L738= | Silent (SNP) | VAF 24/398 reads (6%) | called by muse, mutect2
- FYB1 | c.87T>C p.S29= | Silent (SNP) | VAF 27/688 reads (4%) | called by muse, mutect2
- GLB1L | c.423T>A p.P141= | Silent (SNP) | VAF 34/741 reads (5%) | called by muse, mutect2
- GLI1 | c.1053C>T p.H351= | Silent (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- GNAS | c.1125G>T p.V375= | Silent (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- GPR150 | c.1140C>A p.G380= | Silent (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- GRM6 | c.1845C>T p.I615= | Silent (SNP) | VAF 16/175 reads (9%) | catalogued as rs201328889, COSV51435618; called by muse, mutect2
- IL7R | c.405G>T p.L135= | Silent (SNP) | VAF 46/951 reads (5%) | called by muse, mutect2
- KLHL31 | c.798A>G p.Q266= | Silent (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- LEMD1 | c.501G>C p.V167= | Silent (SNP) | VAF 30/628 reads (5%) | called by muse, mutect2
- LGI1 | c.1201C>T p.L401= | Silent (SNP) | VAF 38/782 reads (5%) | catalogued as COSV65057390; called by muse, mutect2
- LY75-CD302 | c.5454T>C p.A1818= | Silent (SNP) | VAF 26/430 reads (6%) | called by muse, mutect2
- MAGEB16 | c.174A>G p.A58= | Silent (SNP) | VAF 8/179 reads (4%) | catalogued as rs1047308977; called by muse, mutect2
- MAGEB18 | c.960C>A p.A320= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- OR52E4 | c.867C>T p.N289= | Silent (SNP) | VAF 10/145 reads (7%) | called by muse, mutect2
- OTOG | c.7882C>T p.L2628= | Silent (SNP) | VAF 11/202 reads (5%) | catalogued as rs876657558; ClinVar: likely benign; called by muse, mutect2
- PAFAH1B2 | c.525C>T p.T175= | Silent (SNP) | VAF 15/266 reads (6%) | catalogued as rs374387074; called by muse, mutect2
- PRRX1 | c.171G>T p.V57= | Silent (SNP) | VAF 12/159 reads (8%) | called by muse, mutect2
- PTH2R | c.1026C>A p.T342= | Silent (SNP) | VAF 16/446 reads (4%) | catalogued as rs1193907038, COSV99782636; called by muse, mutect2
- SPATA16 | c.555T>C p.S185= | Silent (SNP) | VAF 30/542 reads (6%) | called by muse, mutect2
- STAT6 | c.699C>T p.D233= | Silent (SNP) | VAF 14/183 reads (8%) | called by muse, mutect2
- TAF1 | c.4089G>A p.V1363= (on ENST00000373790 / NM_138923.4; = p.V1384= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/534 reads (7%) | called by muse, mutect2
- TRAPPC9 | c.3381G>A p.K1127= | Silent (SNP) | VAF 26/251 reads (10%) | called by muse, mutect2, varscan2
- TTN | c.82875C>A p.G27625= (on ENST00000591111; = p.G20201= on NM_003319.4) | Silent (SNP) | VAF 42/1024 reads (4%) | called by muse, mutect2
- UGT3A2 | c.1149G>T p.V383= | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- USH2A | c.14256G>T p.V4752= | Silent (SNP) | VAF 29/517 reads (6%) | called by muse, mutect2
- VSTM1 | c.447C>A p.L149= | Silent (SNP) | VAF 16/315 reads (5%) | called by muse, mutect2
- AC006305.1 | n.1048C>A | RNA (SNP) | VAF 22/485 reads (5%) | called by muse, mutect2
- CD8A | c.*199A>T | 3'UTR (SNP) | VAF 44/690 reads (6%) | called by muse, mutect2
- DBNL | c.84-16T>C | Intron (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- DCD | c.*27C>T | 3'UTR (SNP) | VAF 12/210 reads (6%) | catalogued as rs1447283468; called by muse, mutect2
- GOLGA4 | c.163-8378A>T | Intron (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
- IZUMO2 | c.*41A>G | 3'UTR (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
- LCMT1 | c.114-2438G>T | Intron (SNP) | VAF 12/295 reads (4%) | called by muse, mutect2
- MAGI2 | c.3706+13289G>T | Intron (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- MYLK | c.755-18C>T | Intron (SNP) | VAF 46/572 reads (8%) | catalogued as rs748988850; called by muse, mutect2
- NEMF | c.-8G>T | 5'UTR (SNP) | VAF 9/185 reads (5%) | catalogued as rs1566719581; called by muse, mutect2
- VAPB | c.*5044G>T | 3'UTR (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
